ALCHEMIST case ALCH-B28H — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/38186aac-004b-4082-9741-2418ed79cebf

Demographics
Sex at birth: male.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: Age at diagnosis: 66.8 years (24,383 days).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B28H-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B28H-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B28H-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 52; Percent normal cells: 12; Percent necrosis: 15; Percent stromal cells: 13; Percent lymphocyte infiltration: 69; Percent monocyte infiltration: 7; Percent neutrophil infiltration: 11.
- Sample ALCH-B28H-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B28H-TTR1-A-1-0-S1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 50; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
